Somatic mutation profile of tumor specimen TCGA-G9-6370-01A (aliquot TCGA-G9-6370-01A-11D-1786-08) from TCGA case TCGA-G9-6370, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.4 years (19,149 days).
Specimen TCGA-G9-6370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dde13f6e-e2f8-4c43-82e9-62ae02b6b135.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6370-10A (Blood Derived Normal), aliquot TCGA-G9-6370-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62f60f4b-a14d-4def-bbff-bdfb1e527642

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR10P1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs769274514, COSV59006896; called by muse, mutect2
